Somatic mutation profile of tumor specimen 0DUHI1 from CCDI case PBCKRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,276 days).
Specimen 0DUHI1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 395138e9-c4ad-4852-85a7-3518d3b7b283.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHG8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f078754-d9fe-4882-bb58-58affc68f2e4

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 4, Silent 2, Intron 2, Splice Site 1, 5'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1516-1G>A p.X506_splice | Splice Site (SNP) | VAF 32/159 reads (20%) | catalogued as rs1362033885; called by muse, mutect2, varscan2
- CDH23 | c.9447G>T p.E3149D | Missense Mutation (SNP) | VAF 60/512 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs761482604; called by muse, mutect2, varscan2
- COMMD1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1206477550; called by muse, mutect2, varscan2
- LRP1 | c.7349G>A p.G2450D | Missense Mutation (SNP) | VAF 105/380 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54510852; called by muse, mutect2, varscan2
- PLK4 | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 98/940 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1445635869, COSV54637081; ClinVar: likely benign; called by muse, varscan2
- USP28 | c.2818dup p.V940Gfs*26 | Frame Shift Ins (INS) | VAF 284/570 reads (50%) | catalogued as rs1342507221; called by mutect2, varscan2
- NUTM2A | c.2627G>A p.C876Y | Missense Mutation (SNP) | VAF 24/463 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PKHD1 | c.255T>A p.D85E | Missense Mutation (SNP) | VAF 31/1030 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- SH3BP5L | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 64/788 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.945); called by muse, mutect2
- THAP12 | c.1241A>C p.E414A | Missense Mutation (SNP) | VAF 114/751 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- YWHAE | c.390G>C p.R130S | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NMNAT1 | c.48A>T p.S16= | Silent (SNP) | VAF 100/753 reads (13%) | called by muse, mutect2, varscan2
- TBK1 | c.405T>C p.D135= | Silent (SNP) | VAF 86/846 reads (10%) | called by muse, mutect2, varscan2
- C9orf106 | n.468C>A | RNA (SNP) | VAF 101/567 reads (18%) | called by muse, mutect2, varscan2
- EIF3H | c.-21T>A | 5'UTR (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- LDHD | c.*76C>T | 3'UTR (SNP) | VAF 26/186 reads (14%) | called by mutect2, varscan2
- MTRNR2L8 | c.*58A>G | 3'UTR (SNP) | VAF 112/256 reads (44%) | called by muse, mutect2, varscan2
- PAQR6 | c.*156A>G | 3'UTR (SNP) | VAF 34/408 reads (8%) | called by muse, mutect2
- PCGF1 | c.732+19C>T | Intron (SNP) | VAF 55/620 reads (9%) | catalogued as rs1429729645; called by muse, mutect2
- RALGPS2 | c.*19G>A | 3'UTR (SNP) | VAF 201/991 reads (20%) | catalogued as rs1305184516, COSV100860953; called by muse, mutect2, varscan2
- SF3A3 | c.1373-58C>T | Intron (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
